MMRF case MMRF_1235 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/de8855e5-4114-4faf-8134-f6f9ad27c694

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.1 years (20,497 days); ISS stage: II; Days to last known disease status: 1,571 days (4.3 years); Days to last follow up: 1,571 days (4.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 72 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 105 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 254 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7: M Protein 4.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 158 mg/dL; Immunoglobulin G 58.8 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.91 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.84 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.1 mmol/L; Albumin 29 g/L; Total Protein 10.9 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 2.97 mg/dL.
- Day 56 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 4.82 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 1.91 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 12.3 ×10⁹/L; Absolute Neutrophil 8.36 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 6.11 mmol/L.
- Day 170 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 3.88 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.45 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 8.03 mmol/L.
- Day 254 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 8.65 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.94 mmol/L.
- Day 339 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.86 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.46 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 6.77 mmol/L.
- Day 395: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 3.1 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 1.69 µg/mL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.71 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 5.56 mmol/L.
- Day 486: Serum Free Immunoglobulin Light Chain, Kappa 2.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.14 mg/dL; Immunoglobulin G 12.8 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 6.55 mmol/L.
- Day 654 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.81 mg/dL; Immunoglobulin G 15 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.9 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 7.65 mmol/L.
- Day 738: Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.35 mg/dL; Immunoglobulin G 15.2 g/L; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 7.15 mmol/L.
- Day 843 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 4.01 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2.37 µg/mL; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.49 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7.7 g/dL; Glucose 5.23 mmol/L.
- Day 863: Hemoglobin 8.37 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 7.1 g/dL; Glucose 6.38 mmol/L.
- Day 975 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.342 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.324 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 3.68 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 6.38 mmol/L.
- Day 1,059: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.558 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.397 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 4.24 g/L; Immunoglobulin M 0.54 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 37.9 g/L; Total Protein 7.4 g/dL; Glucose 5.61 mmol/L.
- Day 1,156: Lactate Dehydrogenase 1.7 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 1.98 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 6.11 mmol/L.
- Day 1,207 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.06 mg/dL; Immunoglobulin G 21.3 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 5.64 g/L; Beta 2 Microglobulin 1.83 µg/mL; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.97 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 8.2 g/dL; Glucose 4.62 mmol/L.
- Day 1,388: M Protein 0 g/dL; Immunoglobulin G 15.2 g/L; Immunoglobulin A 4.19 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 1.67 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 8.42 mmol/L.
- Day 1,571 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.5 mg/dL; Immunoglobulin G 16.2 g/L; Immunoglobulin A 5.67 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 1.53 µg/mL; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.49 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day -7: Weight: 87 kg; Height: 174 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lymphoma.

Biospecimens (4 samples)
- Sample MMRF_1235_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1235_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
- Sample MMRF_1235_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 170 days.
- Sample MMRF_1235_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 170 days.
